Gene-level copy-number profile of tumor specimen TCGA-E7-A4XJ-01A from TCGA case TCGA-E7-A4XJ, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 66.5 years (24,279 days).
Specimen TCGA-E7-A4XJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.6a7b271a-2f04-4ffe-82ce-e7b87622d135.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-E7-A4XJ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/53dfe6a1-c4c0-4612-9ef7-96ef99e931fa

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,279; copy number 2: 56,447; copy number 19: 24; copy number 20: 64; copy number 21: 5; copy number 23: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-E7-A4XJ-01A-11D-A26L-01): tumor purity 0.84, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 94 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:86,866,415–87,615,219, 1 gene, copy number 23 (within-gene range 2–23): CNBD1.
- chr8:99,960,936–102,124,907, 59 genes, copy number 20 (within-gene range 2–20): RGS22, SNORD77B, AC021590.1, FBXO43, POLR2K, SPAG1, Y_RNA, AC025647.1, Y_RNA, RNF19A, AP001574.1, AP003472.1, MIR4471, AP003472.2, AP000424.1, AP000424.2, ANKRD46, GAPDHP62, SNX31, AP001205.1, RNU6-1092P, PABPC1, MIR7705, RNU6ATAC41P, Y_RNA, RPS20P23, RNU4-83P, RPS26P6, Metazoa_SRP, AC027373.1, YWHAZ, RN7SL685P, FLJ42969, AP003469.2, AP003469.1, RN7SKP249, AP003469.3, ZNNT1, ZNF706, AP001330.4, AP001330.2, LINC02844, AP001330.5, AP001330.1, RNU7-67P, AP001330.3, NACA4P, DUXAP2, LINC02845, RN7SL563P, AP001208.1, AP001207.3, GRHL2, AP001207.2, AP001207.1, NCALD, AP000426.1, AP001329.1, PDCL3P2.
- chr8:119,711,830–120,373,573, 11 genes, copy number 19 (within-gene range 2–19): RN7SKP153, TAF2, AP005717.2, DSCC1, AC021945.1, RN7SL396P, AP005717.1, DEPTOR, RNA5SP277, AC091563.1, COL14A1.
- chr8:126,556,323–127,419,050, 1 gene, copy number 21 (within-gene range 2–21): PCAT1.
- chr8:126,766,196–127,227,541, 4 genes, copy number 21 (within-gene range 2–21): AC024382.1, CASC19, PRNCR1, AC020688.1.
- chr8:127,289,817–128,187,101, 18 genes, copy number 19–20 (within-gene range 2–20): CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207.

Autosomal genes at a single copy (total copy number 1): 892. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
